Somatic mutation profile of tumor specimen TCGA-16-0848-01A (aliquot TCGA-16-0848-01A-01D-1492-08) from TCGA case TCGA-16-0848, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.1 years (20,848 days).
Specimen TCGA-16-0848-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85c66fa1-9f67-41ac-84c0-704080197413.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-0848-10A (Blood Derived Normal), aliquot TCGA-16-0848-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d0799f7-43b6-4321-93bd-313fde9f010f

The open-access MAF lists 357 somatic variants for this specimen: 257 protein-altering or splice-affecting, 95 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 236, Silent 95, Nonsense Mutation 13, Frame Shift Del 4, Intron 3, 3'Flank 2, Splice Site 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F9 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852233, CM940466, CM940467, CM960576, COSV54382023, COSV99496796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 38/93 reads (41%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 35/57 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 97/125 reads (78%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs370246921, COSV99966651; called by muse, mutect2, varscan2
- ABCC10 | c.2263G>A p.A755T (on ENST00000372530 / NM_001198934.2; = p.A727T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as rs761988294, COSV99767937; called by muse, mutect2, varscan2
- ABHD16B | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV99410869; called by muse, mutect2, varscan2
- ABHD5 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs143489624; called by muse, mutect2, varscan2
- ABI2 | c.1399G>A p.E467K (on ENST00000295851 / NM_001375719.1; = p.E429K on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99652244; called by muse, mutect2, varscan2
- ACOX1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1302158047, COSV53135864, COSV99503956; called by muse, mutect2, varscan2
- ADAM10 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV53051272; called by muse, mutect2, varscan2
- ADCK2 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as rs919343786, COSV99301855; called by muse, mutect2, varscan2
- ADCY1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs768415059, COSV52029771; called by muse, mutect2, varscan2
- ADGRA2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as rs371864107; called by muse, varscan2
- AGAP1 | c.2138G>A p.R713H (on ENST00000304032 / NM_001037131.3; = p.R660H on NM_014914.5) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs766895412, COSV58334446; called by muse, mutect2, varscan2
- AKAP13 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs774873759, COSV63473490; called by muse, mutect2, varscan2
- ANK2 | c.8728G>A p.V2910M | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.251); catalogued as rs748400535, COSV100004068, COSV52170217; called by muse, mutect2, varscan2
- ANO6 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); catalogued as COSV100263858; called by muse, mutect2
- APAF1 | c.2207G>A p.R736Q (on ENST00000551964 / NM_181861.2; = p.R725Q on NM_001160.3) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.049); catalogued as rs751875283, COSV59663045; called by muse, mutect2, varscan2
- APBA1 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454451021, COSV55237715, COSV99596318; called by muse, mutect2, varscan2
- APLP2 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.211); catalogued as rs371634970; called by muse, mutect2, varscan2
- AQP12B | c.556G>A p.V186I (on ENST00000621682; = p.V198I on NM_001102467.2) | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs746833612, COSV101315927; called by muse, mutect2
- AREL1 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100707649; called by muse, mutect2, varscan2
- AREL1 | c.1101C>G p.F367L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100707650; called by muse, mutect2, varscan2
- ARHGAP32 | c.4714G>A p.E1572K (on ENST00000310343 / NM_001378025.1; = p.E1223K on NM_014715.4) | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs200206728, COSV59843905; called by muse, mutect2, varscan2
- ARHGEF19 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.732); catalogued as rs773105913, COSV99580755; called by muse, varscan2
- ASTL | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs144613777, COSV60904941; called by mutect2, varscan2
- ASTN2 | c.3025C>T p.R1009C (on ENST00000313400 / NM_001365069.1; = p.R958C on NM_014010.5) | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs145202780, COSV56001308; called by muse, mutect2, varscan2
- ATP1A1 | c.2077A>G p.T693A | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99814758; called by muse, mutect2, varscan2
- B4GALNT3 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs578203139, COSV99843573; called by muse, mutect2
- B4GALNT4 | c.2444G>A p.R815H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.096); catalogued as rs969948443, COSV57322055; called by muse, mutect2, varscan2
- BCAR3 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 15/144 reads (10%) | catalogued as rs1557836909, COSV53073095; called by muse, mutect2, varscan2
- BDKRB1 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as rs761261697, COSV53705645; called by muse, mutect2, varscan2
- BORCS5 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs757870676, COSV100056344, COSV53802857; called by muse, mutect2, varscan2
- BRINP3 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748757778, COSV66531106; called by muse, mutect2
- BRMS1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751370154, COSV100240375; called by muse, mutect2, varscan2
- CANT1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs886053526, COSV100185374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASKIN1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs908743049, COSV58876840; called by muse, mutect2, varscan2
- CBLL1 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.448); catalogued as COSV99755909; called by muse, mutect2, varscan2
- CCDC142 | c.2203C>T p.R735C (on ENST00000393965 / NM_001365575.2; = p.R728C on NM_032779.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1349047936; called by muse, varscan2
- CCDC80 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs775543007, COSV52818945; called by muse, mutect2, varscan2
- CDH15 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.943); catalogued as rs763753067, COSV57021649; called by muse, mutect2, varscan2
- CEP131 | c.2072G>A p.R691H (on ENST00000269392 / NM_001319228.2; = p.R688H on NM_014984.4) | Missense Mutation (SNP) | VAF 115/422 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs752096772, COSV99488993; called by muse, mutect2, varscan2
- CEP55 | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101017144; called by muse, mutect2, varscan2
- CEP63 | c.1151A>G p.H384R | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs763437947, COSV100133091; called by muse, mutect2, varscan2
- CHCHD5 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100260917; called by muse, mutect2
- CLDN4 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs371121791; called by muse, mutect2
- CLDN4 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs368855545, COSV52897401; called by muse, mutect2, varscan2
- CLRN2 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200144103, COSV55549304; called by muse, mutect2, varscan2
- CNOT1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs745954288, COSV57776502; called by muse, mutect2
- CNR2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as rs200619419, COSV100991589; called by muse, mutect2
- CNTNAP5 | c.3502G>A p.V1168I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375640846, CM1010519; called by muse, mutect2, varscan2
- COL24A1 | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs924339107, COSV100993956; called by muse, mutect2, varscan2
- COL6A1 | c.2965G>A p.G989S | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs138652066; called by muse, mutect2, varscan2
- CORIN | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs756151201, COSV56696840, COSV99904411; called by muse, mutect2, varscan2
- CPA5 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 17/309 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV100812456; called by muse, mutect2
- CREB3L3 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs777963164, COSV50217377, COSV99314503; called by muse, mutect2, varscan2
- CRLF2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs370445430, COSV101053825; called by muse, mutect2
- CSMD2 | c.7384C>T p.R2462C | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs938410594, COSV53978139; called by muse, mutect2, varscan2
- CSMD2 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs761180145, COSV53892340; called by muse, mutect2, varscan2
- CTDSP1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99812085; called by muse, mutect2, varscan2
- CYP1B1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs899277811, COSV99572830; called by muse, mutect2, varscan2
- CYP26B1 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as rs200556766, COSV50012099; called by muse, mutect2, varscan2
- CYP2B6 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs752695347, COSV57844965; called by muse, mutect2, varscan2
- DCTN4 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 35/387 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs945042828, COSV101437583; called by muse, mutect2
- DENND2B | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1287941055, COSV100567819; called by muse, mutect2, varscan2
- DHX35 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376209770; called by muse, mutect2, varscan2
- DIS3L | c.962C>T p.S321L (on ENST00000319212 / NM_001143688.3; = p.S238L on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs144553500; called by muse, mutect2, varscan2
- DNAAF5 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as rs200034358, COSV52414600, COSV99860278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMBP | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 97/136 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV100144385; called by muse, mutect2, varscan2
- DNMT1 | c.4738G>A p.V1580M | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61580968; called by muse, varscan2
- DNTT | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779136442, COSV100960684, COSV64523888; called by muse, mutect2, varscan2
- DOCK10 | c.5473C>T p.R1825* | Nonsense Mutation (SNP) | VAF 88/216 reads (41%) | catalogued as rs759216323, COSV99291503; called by muse, mutect2, varscan2
- DOCK4 | c.5843G>A p.R1948Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.043); catalogued as rs771643939, COSV101447963; called by muse, mutect2, varscan2
- DPP4 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149643982, COSV62106254; called by muse, mutect2, varscan2
- DST | c.18574G>A p.E6192K (on ENST00000361203 / NM_001374722.1; = p.E3889K on NM_015548.5) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.847); catalogued as rs756660501, COSV54999095; called by muse, mutect2, varscan2
- E2F2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419056781, COSV62276348; called by muse, mutect2, varscan2
- EBF1 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs778162720, COSV58180087; called by mutect2, varscan2
- ELMOD3 | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100226479, COSV59772880; called by muse, mutect2, varscan2
- ETAA1 | c.1906A>T p.I636L | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99712934; called by muse, varscan2
- EVPL | c.3908G>A p.R1303H | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV56913625; called by muse, mutect2, varscan2
- EXTL3 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as rs141948891; called by muse, mutect2, varscan2
- FCGBP | c.12046C>T p.R4016C | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs1460438828; called by muse, mutect2, varscan2
- FHOD3 | c.3025G>A p.D1009N (on ENST00000359247 / NM_001281739.3; = p.D1026N on NM_025135.5) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs554487359, COSV57165602, COSV99941725; called by muse, mutect2, varscan2
- FLOT1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV52544455; called by muse, mutect2
- FMN1 | c.3880G>C p.E1294Q (on ENST00000616417 / NM_001277313.2; = p.E1071Q on NM_001103184.4) | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as COSV100569283, COSV57922647; called by muse, mutect2, varscan2
- FNDC1 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs376771645; called by muse, mutect2, varscan2
- FOXJ3 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV62362329; called by muse, mutect2
- FRMPD4 | c.3874C>T p.P1292S | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.859); catalogued as rs780443219, COSV101044011; called by muse, mutect2, varscan2
- FTSJ1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs76994219, COSV99191451; called by muse, mutect2, varscan2
- FYCO1 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs149818406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAD1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.149); catalogued as COSV60151756; called by muse, mutect2, varscan2
- GBP3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs145016759; called by muse, mutect2, varscan2
- GBX2 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs61743573, COSV100103611; called by muse, mutect2
- GCC1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1480934661, COSV99133925; called by muse, mutect2
- GFM1 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1232426531, COSV99963165; called by muse, mutect2
- GGNBP2 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs201874238; called by muse, mutect2, varscan2
- GGT1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs113647199, COSV50646320; called by muse, mutect2, varscan2
- GHSR | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99577220; called by muse, mutect2
- GLB1L | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs745358178, COSV99850876; called by muse, mutect2
- GPATCH8 | c.2132G>A p.R711H | Missense Mutation (SNP) | VAF 47/403 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); catalogued as rs749352671, COSV59193364; called by muse, mutect2, varscan2
- GPLD1 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs978168751, COSV57755613; called by muse, mutect2, varscan2
- GPR108 | c.857+1G>A p.X286_splice (on ENST00000264080 / NM_001080452.1; = p.X44_splice on NM_020171.2) | Splice Site (SNP) | VAF 10/152 reads (7%) | catalogued as rs965165867, COSV99901528; called by muse, mutect2
- GRIN2B | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1428234478, COSV74204916; called by muse, mutect2, varscan2
- GRIP1 | c.2906G>A p.R969Q (on ENST00000359742 / NM_001379345.1; = p.R917Q on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.394); catalogued as rs781673053, COSV99670915; called by muse, mutect2
- GSE1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs540734949, COSV99496901; called by muse, mutect2, varscan2
- H1-3 | c.52A>G p.T18A | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1225421203, COSV99768886; called by muse, mutect2, varscan2
- HERC2 | c.6389C>T p.P2130L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs751735371, COSV99876609; called by muse, mutect2, varscan2
- HIP1 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 21/632 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373608095, COSV61187980; called by muse, mutect2
- IFI16 | c.1825G>T p.E609* (on ENST00000295809 / NM_001364867.2; = p.E553* on NM_005531.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 47/142 reads (33%) | catalogued as COSV99858141; called by muse, mutect2, varscan2
- IGHMBP2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769046350, COSV99662537, COSV99662681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGSF9B | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs755959469, COSV100318370; called by muse, mutect2, varscan2
- INPP5D | c.3485G>A p.R1162H (on ENST00000445964 / NM_001017915.3; = p.R1161H on NM_005541.5) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64035320; called by muse, mutect2, varscan2
- IQSEC3 | c.928G>A p.G310S (on ENST00000538872 / NM_001170738.2; = p.G7S on NM_015232.1) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100407512, COSV100407597; called by muse, mutect2, varscan2
- IRX1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV57357723; called by muse, mutect2, varscan2
- IRX1 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV57358638; called by muse, mutect2
- ITGA8 | c.1970+1G>A p.X657_splice | Splice Site (SNP) | VAF 28/46 reads (61%) | catalogued as rs749220565, COSV100959707; called by muse, mutect2, varscan2
- ITGAE | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs747958723, COSV99561512; called by muse, mutect2
- KCNAB1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as COSV67484538; called by muse, mutect2, varscan2
- KCNB1 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1338339252, COSV65568401; called by muse, mutect2, varscan2
- KCNJ11 | c.334A>C p.T112P | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV100379219; called by muse, mutect2, varscan2
- KCNJ4 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1168216725, COSV100340995; called by muse, mutect2, varscan2
- KCNQ3 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753513804, COSV101196417; called by muse, mutect2, varscan2
- KCNQ4 | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs761479115, COSV100714415; called by muse, mutect2, varscan2
- KLHL18 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1171041482, COSV99231275; called by muse, mutect2, varscan2
- KLHL32 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1469633500, COSV100987486; called by muse, mutect2, varscan2
- KNTC1 | c.5739G>T p.V1913= | Splice Region (SNP) | VAF 10/87 reads (11%) | catalogued as COSV100338790; called by muse, varscan2
- KRT19 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746266333, COSV99563270; called by muse, mutect2
- L1CAM | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 157/189 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs201311640, CM151720, COSV100649453; called by muse, mutect2, varscan2
- LAX1 | c.167G>A p.C56Y | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV100920094; called by muse, mutect2
- LENG8 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as rs113629258, COSV99045091; called by muse, mutect2
- LILRB4 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs766142180, COSV54408647, COSV99553791; called by muse, mutect2, varscan2
- LPCAT1 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as rs1339369321, COSV99359340; called by muse, mutect2, varscan2
- LPO | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1442109405, COSV99229358; called by muse, mutect2, varscan2
- LRCH3 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 52/149 reads (35%) | catalogued as rs754999037, COSV100605081; called by muse, mutect2, varscan2
- LRFN3 | c.1633G>A p.G545S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99873583; called by muse, mutect2, varscan2
- LRP2 | c.13754G>A p.R4585Q | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs764511347, COSV55540466; called by muse, mutect2, varscan2
- MACC1 | c.1570A>G p.K524E | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100256255; called by muse, mutect2, varscan2
- MAP3K10 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1353418800, COSV99454823; called by muse, mutect2, varscan2
- MAP3K12 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs147211101; called by muse, mutect2, varscan2
- MAP3K15 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 81/105 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs766154880, COSV58830904, COSV58839303; called by muse, mutect2, varscan2
- MAPT | c.1678G>A p.A560T (on ENST00000262410 / NM_001377265.1; = p.A168T on NM_005910.5) | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs773178106, COSV52239314; called by muse, mutect2
- MARCHF2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as rs763102811, COSV99294889; called by muse, mutect2, varscan2
- MCM3AP | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99387481; called by muse, mutect2, varscan2
- MCM4 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100031834; called by muse, mutect2, varscan2
- MCRS1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs746343401, COSV57792538; called by muse, mutect2, varscan2
- MECR | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs759114736, COSV99747397; called by muse, mutect2
- MMP15 | c.1650G>T p.K550N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99539718; called by muse, mutect2, varscan2
- MMP21 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as COSV64290161; called by muse, mutect2, varscan2
- MOGS | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 114/326 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs752641712, COSV51968934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MORN3 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs747756614, COSV62507817; called by muse, mutect2, varscan2
- MRE11 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs587781378, COSV100120030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSH6 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as rs747477669, COSV99316899; called by muse, mutect2, varscan2
- MYH3 | c.5648C>T p.A1883V | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs770070846, COSV56866464; called by muse, mutect2, varscan2
- MYO10 | c.6130C>T p.R2044C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771834995, COSV99946213; called by muse, mutect2, varscan2
- NAV1 | c.3632del p.K1211Rfs*17 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs770039235; called by mutect2, varscan2
- NTN4 | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | catalogued as rs1403390954, COSV59224570; called by muse, mutect2, varscan2
- NUP205 | c.2626G>C p.V876L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.362); catalogued as COSV53664641, COSV99607560; called by muse, mutect2
- OBSCN | c.11162G>A p.R3721K | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV99483983; called by muse, mutect2
- OTX2 | c.106C>T p.R36W (on ENST00000408990 / NM_172337.3; = p.R44W on NM_021728.4) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD124838, COSV100258088; called by muse, mutect2, varscan2
- PAK5 | c.2060A>G p.Q687R | Missense Mutation (SNP) | VAF 112/290 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100781661; called by muse, mutect2, varscan2
- PARP1 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs759579130, COSV100829045; called by muse, mutect2, varscan2
- PCDHA12 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.435); catalogued as rs1554168978, COSV56488024; called by muse, mutect2, varscan2
- PCDHB5 | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV50651091; called by muse, mutect2, varscan2
- PCDHGB4 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763321545, COSV53912675; called by muse, mutect2, varscan2
- PCDHGB4 | c.2107G>A p.V703M | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV53966571; called by muse, mutect2
- PCLO | c.6961A>G p.R2321G | Missense Mutation (SNP) | VAF 100/430 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV100437457; called by muse, mutect2, varscan2
- PGPEP1 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.266); catalogued as rs201898854, COSV99416408, COSV99416696; called by muse, mutect2, varscan2
- PIK3R6 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100266850; called by muse, mutect2, varscan2
- PPFIA3 | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99418305; called by muse, mutect2, varscan2
- PPFIBP2 | c.2536A>G p.S846G | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs757189159, COSV100206934; called by muse, mutect2, varscan2
- PPP1R12C | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99670263; called by muse, mutect2, varscan2
- PPP4R4 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs1006379723, COSV58553766; called by muse, mutect2, varscan2
- PRG4 | c.3917G>A p.R1306H | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1557970634, COSV100798311; called by muse, mutect2, varscan2
- PRICKLE2 | c.1790G>A p.R597Q (on ENST00000295902; = p.R541Q on NM_198859.4) | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs768214855, COSV55765700; called by muse, mutect2, varscan2
- PRKDC | c.10870G>T p.G3624C | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV100042703; called by muse, mutect2, varscan2
- PRSS16 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.889); catalogued as rs1330907157, COSV100041975; called by muse, mutect2, varscan2
- PSG6 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51829705, COSV99414507; called by muse, mutect2
- PTGER3 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 73/220 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as rs777755530, COSV60690336; called by muse, mutect2, varscan2
- PTPN21 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100162504; called by muse, mutect2
- PTPRF | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.16); catalogued as rs1189049815, COSV63442919; called by muse, mutect2, varscan2
- QTRT1 | c.1078G>A p.V360I | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs754147172, COSV99139112; called by muse, mutect2, varscan2
- RAD54B | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs746694103, COSV60250792; called by muse, mutect2, varscan2
- RAD54L | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as rs147366486; called by muse, mutect2, varscan2
- RERE | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.234); catalogued as rs764364709, COSV61942929; called by muse, mutect2, varscan2
- RESF1 | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as rs763753313, COSV57019973; called by muse, mutect2, varscan2
- RFC2 | c.1057G>A p.A353T (on ENST00000055077 / NM_181471.3; = p.A319T on NM_002914.4) | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as COSV50017273; called by muse, mutect2
- RFTN2 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs757592246, COSV54388942; called by muse, mutect2, varscan2
- RGPD1 | c.4067G>A p.G1356D (on ENST00000409776; = p.G1364D on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/357 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.378); catalogued as COSV101233692; called by muse, mutect2, varscan2
- RHBDF2 | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1196107833, COSV99166265; called by muse, mutect2, varscan2
- RIF1 | c.4331G>A p.R1444H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs765365931, COSV99691211; called by muse, mutect2, varscan2
- RNF220 | c.1475T>C p.F492S | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100132257; called by muse, mutect2, varscan2
- RNF40 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs765570681, COSV61215883; called by muse, mutect2, varscan2
- ROCK2 | c.3638A>T p.Q1213L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100255913; called by muse, mutect2, varscan2
- RRNAD1 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748934059, COSV100836998; called by muse, mutect2, varscan2
- RSPRY1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs748673463, COSV68028895; called by muse, mutect2
- RTN4RL1 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs889815822, COSV100486803; called by muse, mutect2, varscan2
- RXFP3 | c.803A>G p.H268R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV100347789; called by muse, varscan2
- SCML1 | c.643C>T p.R215W (on ENST00000380041 / NM_001037540.3; = p.R188W on NM_006746.6) | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101193977; called by muse, mutect2, varscan2
- SCN2A | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs745774658, COSV51846021; ClinVar: uncertain significance; called by muse, mutect2
- SDK1 | c.2458C>T p.R820W | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs759323106, COSV67379581; called by muse, mutect2, varscan2
- SDS | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 35/329 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs1199824791, COSV55109071; called by muse, mutect2, varscan2
- SEC14L5 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1168677604, COSV52043650; called by muse, mutect2, varscan2
- SENP7 | c.1931T>A p.I644K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100053853; called by muse, mutect2
- SESTD1 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs749484642, COSV100090882; called by muse, mutect2, varscan2
- SETD7 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV56800224; called by muse, mutect2, varscan2
- SGSM1 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768586256, COSV68509802; called by muse, mutect2, varscan2
- SLC14A2 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs1462386004, COSV54910627; called by muse, mutect2, varscan2
- SLC2A1 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 102/275 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1387242348, CM118205, COSV100995962; called by muse, mutect2, varscan2
- SLC38A11 | c.290G>A p.R97H (on ENST00000409149 / NM_001351539.1; = p.R75H on NM_173512.2) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs914142729, COSV58053143; called by muse, varscan2
- SLC39A9 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.708); catalogued as rs376565540, COSV99220693; called by muse, mutect2, varscan2
- SLC5A12 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54821476; called by muse, mutect2, varscan2
- SLCO1B1 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as rs769518588, COSV57013212; ClinVar: uncertain significance; called by muse, mutect2
- SP2 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.937); catalogued as rs774644043, COSV100947186; called by muse, mutect2
- SPEN | c.5749C>T p.R1917C | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1298127512, COSV65357260; called by muse, mutect2, varscan2
- SPPL2B | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101476116; called by muse, mutect2, varscan2
- SPTA1 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 91/238 reads (38%) | catalogued as COSV100935524; called by muse, mutect2, varscan2
- SREBF2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.526); catalogued as COSV100761547; called by muse, mutect2
- STAG1 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs749698375, COSV99366878; called by muse, mutect2, varscan2
- SUPT6H | c.2984G>A p.R995Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1379806291, COSV100112687, COSV58928187; called by muse, mutect2, varscan2
- SV2C | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs759085527, COSV59227182; called by muse, mutect2, varscan2
- SYNPO2 | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs918346408, COSV100206350; called by muse, varscan2
- SYT16 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761346026, COSV70855321; called by muse, varscan2
- TAP2 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs771932254, HM0717, COSV66498536; called by muse, mutect2, varscan2
- TCEAL6 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.933); catalogued as rs781896186, COSV101036037; called by muse, mutect2, varscan2
- TEAD4 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs201149385, COSV63281005; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2173C>T p.H725Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV99305509; called by muse, mutect2, varscan2
- THAP11 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 118/315 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99534593; called by muse, mutect2, varscan2
- TKT | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); catalogued as rs782692158, COSV99965151; called by muse, mutect2, varscan2
- TRAPPC5 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs774090407, COSV58039412, COSV58040334; called by muse, mutect2, varscan2
- TTC37 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as rs1352204815, COSV62456939; called by muse, mutect2, varscan2
- TTN | c.58406C>T p.A19469V (on ENST00000591111; = p.A12045V on NM_003319.4) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | PolyPhen benign (0.035); catalogued as rs370687831; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- TUT1 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99545579; called by muse, mutect2, varscan2
- TYR | c.740G>A p.C247Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99635263; called by muse, mutect2
- UBR2 | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100867518; called by muse, mutect2, varscan2
- UNC79 | c.6757C>T p.R2253* (on ENST00000393151 / NM_001346218.2; = p.R2076* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as COSV56383345; called by muse, mutect2, varscan2
- USP22 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as rs752874123, COSV54949448; called by muse, mutect2, varscan2
- USP40 | c.2102C>T p.T701M | Missense Mutation (SNP) | VAF 91/241 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as rs1047445786, COSV52484662; called by muse, mutect2, varscan2
- VWA2 | c.1192G>C p.G398R | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100073960; called by muse, mutect2, varscan2
- WDR6 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs762832120, COSV100556705; called by muse, mutect2, varscan2
- WDR83 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs759704090, COSV99269752; called by muse, mutect2, varscan2
- WDR86 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs750930575, COSV100561422; called by muse, mutect2, varscan2
- XRCC6 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV100777913; called by muse, mutect2, varscan2
- ZDHHC18 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1198469791, COSV100938871; called by muse, mutect2, varscan2
- ZGRF1 | c.4408C>T p.R1470W | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs768750034, COSV71393035; called by muse, mutect2, varscan2
- ZNF101 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs753717367, COSV58908780; called by muse, mutect2, varscan2
- ZNF292 | c.3400C>T p.R1134C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs755801731, COSV60541886; called by muse, mutect2, varscan2
- ZNF490 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.486); catalogued as rs773377509, COSV61007592; called by muse, mutect2, varscan2
- ZNF628 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs777692931, COSV99220275; called by muse, mutect2, varscan2
- ZNF644 | c.2518G>A p.V840I | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs267598765, COSV61347327; called by muse, mutect2, varscan2
- ZNF713 | c.932G>A p.R311H (on ENST00000633730 / NM_001366796.2; = p.R324H on NM_182633.3) | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs772724043, COSV70056566; called by muse, mutect2
- ZNF804B | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs781202005, COSV60814724; called by muse, mutect2, varscan2
- BCL11A | c.994G>A p.A332T (on ENST00000335712 / NM_001365609.1; = p.A366T on NM_018014.4) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ESF1 | c.494dup p.N165Kfs*2 | Frame Shift Ins (INS) | VAF 11/68 reads (16%) | called by mutect2, varscan2
- RNF39 | c.664del p.M222Cfs*5 | Frame Shift Del (DEL) | VAF 12/140 reads (9%) | called by mutect2, pindel
- SLC9B1 | c.331del p.I111Ffs*9 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- ABCA2 | c.1935C>T p.D645= (on ENST00000614293; = p.D615= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as rs563442914, COSV99688398; called by muse, mutect2, varscan2
- ACTC1 | c.108C>T p.I36= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs1457769757, COSV99292117; called by muse, mutect2
- ADGRA1 | c.120C>T p.I40= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs751844986, COSV66930793; called by muse, mutect2, varscan2
- ADGRF3 | c.1803C>T p.F601= (on ENST00000311519 / NM_001145168.1; = p.F402= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs933057001, COSV61051678; called by muse, mutect2
- ANO1 | c.2619G>A p.S873= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as rs1021543138, COSV100797399; called by muse, mutect2, varscan2
- B3GNT9 | c.1140C>T p.H380= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1159918609, COSV99531638; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3273C>T p.A1091= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs569227686, COSV100863929; ClinVar: likely benign; called by muse, mutect2, varscan2
- BTNL8 | c.105C>T p.D35= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs371053690; called by muse, mutect2, varscan2
- C8G | c.381C>T p.V127= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs141247513; called by muse, mutect2, varscan2
- CANT1 | c.831G>A p.P277= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs370450411; called by muse, varscan2
- CCN2 | c.561G>A p.T187= | Silent (SNP) | VAF 7/109 reads (6%) | catalogued as rs940201069, COSV100915360; called by muse, mutect2
- CDH5 | c.2328G>A p.S776= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV58517896; called by muse, mutect2, varscan2
- CECR2 | c.2376C>T p.A792= (on ENST00000342247 / NM_001290047.2; = p.A609= on NM_001290046.1) | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs775554817, COSV52838649, COSV99379056; called by muse, mutect2, varscan2
- CETN1 | c.282G>A p.T94= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV59121212; called by muse, mutect2, varscan2
- CHAF1B | c.690C>T p.D230= | Silent (SNP) | VAF 78/302 reads (26%) | catalogued as rs373907249; called by muse, mutect2, varscan2
- CNGA3 | c.1404C>T p.I468= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs1465351825, COSV55628623; called by muse, mutect2, varscan2
- CNGB3 | c.768G>A p.A256= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs767128005, COSV60689772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A2 | c.2856C>T p.F952= | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as rs747574881, COSV64625998; ClinVar: likely benign; called by muse, mutect2, varscan2
- CORO2B | c.177C>T p.S59= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as rs542742755, COSV55953636; called by muse, mutect2, varscan2
- DDX41 | c.708G>A p.T236= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs920310571, COSV100286820; called by muse, mutect2, varscan2
- DIP2A | c.1083C>T p.A361= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs376861315; called by muse, mutect2, varscan2
- EGR3 | c.846C>T p.C282= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs1460260788, COSV57833247; called by muse, mutect2, varscan2
- ESYT2 | c.1971C>T p.L657= (on ENST00000613624; = p.L581= on NM_020728.3) | Silent (SNP) | VAF 15/276 reads (5%) | catalogued as rs780677876, COSV51750572, COSV99277234; called by muse, mutect2
- FAM155A | c.702G>A p.L234= | Silent (SNP) | VAF 9/192 reads (5%) | catalogued as COSV101030194; called by muse, mutect2
- FASLG | c.153G>A p.P51= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs147380045; ClinVar: likely benign; called by muse, varscan2
- FIZ1 | c.672C>T p.D224= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1195920359, COSV99684732; called by muse, mutect2, varscan2
- FO393400.1 | c.282G>A p.A94= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs764422132, COSV54071718; called by muse, mutect2, varscan2
- FOXO3 | c.1023G>A p.A341= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs370562790; called by muse, mutect2, varscan2
- FSIP2 | c.19458T>C p.N6486= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs776555925, COSV100556399; called by muse, mutect2, varscan2
- GALNT10 | c.1203C>T p.Y401= | Silent (SNP) | VAF 60/189 reads (32%) | catalogued as rs557019914, COSV51728790; called by muse, mutect2, varscan2
- GALNT15 | c.837C>T p.L279= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs374048513; called by muse, mutect2, varscan2
- GIT2 | c.312G>A p.A104= | Silent (SNP) | VAF 63/206 reads (31%) | catalogued as rs370200013; called by muse, mutect2, varscan2
- GRWD1 | c.978C>T p.G326= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as rs763482368, COSV53517736; called by muse, mutect2, varscan2
- HECW2 | c.681C>T p.H227= | Silent (SNP) | VAF 136/362 reads (38%) | catalogued as rs760309516, COSV99647110, COSV99648899; called by muse, mutect2, varscan2
- HEPHL1 | c.318C>T p.A106= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs576118929, COSV100244386; called by muse, mutect2, varscan2
- HMCN1 | c.15585A>G p.E5195= | Silent (SNP) | VAF 64/152 reads (42%) | catalogued as COSV99635308; called by muse, mutect2, varscan2
- HSPG2 | c.2361G>A p.T787= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs750614056, COSV101021189; called by muse, mutect2, varscan2
- IL20RB | c.177G>A p.A59= | Silent (SNP) | VAF 102/265 reads (38%) | catalogued as rs959336573, COSV100291273; called by muse, mutect2, varscan2
- IL3RA | c.57G>A p.T19= | Silent (SNP) | VAF 68/246 reads (28%) | catalogued as rs779974164, COSV100452385; called by muse, mutect2, varscan2
- IRX6 | c.1194C>T p.S398= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV51860348; called by muse, mutect2
- ITSN2 | c.666G>A p.S222= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs778654550, COSV100744134; called by muse, mutect2, varscan2
- KMT2B | c.3723C>T p.H1241= | Silent (SNP) | VAF 77/306 reads (25%) | catalogued as rs762663354, COSV99720583; called by muse, mutect2, varscan2
- LRRC25 | c.90G>A p.A30= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100170607; called by muse, mutect2, varscan2
- MAN1C1 | c.1467C>T p.Y489= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs944298097, COSV99848917; called by muse, mutect2, varscan2
- MEGF6 | c.1128T>C p.C376= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV99621335; called by muse, mutect2
- MPPE1 | c.1020G>A p.T340= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs558317965, COSV52327051; called by muse, mutect2, varscan2
- MRGPRX4 | c.135C>T p.N45= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as rs746707315, COSV100049842; called by muse, mutect2, varscan2
- MSANTD1 | c.351C>T p.S117= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as rs776594697, COSV101433676; called by muse, mutect2, varscan2
- MTA1 | c.849C>T p.D283= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs782204369, COSV58759514; called by muse, mutect2, varscan2
- MTARC1 | c.870G>A p.P290= | Silent (SNP) | VAF 49/168 reads (29%) | catalogued as rs374227225, COSV65055600; called by muse, mutect2, varscan2
- MYBPC1 | c.57G>A p.P19= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs772946518, COSV100638254; called by muse, mutect2, varscan2
- MYH14 | c.504C>T p.H168= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as rs747568164, COSV51819750; called by muse, mutect2, varscan2
- MYOZ1 | c.444G>A p.A148= | Silent (SNP) | VAF 50/70 reads (71%) | catalogued as rs779906026, COSV63772633; called by muse, mutect2, varscan2
- NAT9 | c.372C>T p.A124= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs555556955, COSV52853491; called by muse, mutect2, varscan2
- NAV2 | c.1920G>A p.A640= (on ENST00000396087 / NM_001244963.2; = p.A617= on NM_145117.5) | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs531952049, COSV100586945; called by muse, mutect2
- NDUFS7 | c.399G>A p.A133= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs144868423; called by muse, mutect2, varscan2
- NFATC1 | c.702G>A p.P234= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as rs754626986, COSV99502485; called by muse, mutect2, varscan2
- NPR3 | c.375C>T p.G125= | Silent (SNP) | VAF 13/152 reads (9%) | catalogued as COSV99423813; called by muse, mutect2
- NPRL2 | c.738C>T p.C246= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99205924; called by muse, mutect2, varscan2
- NRSN2 | c.39C>T p.R13= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs368963058; called by muse, mutect2, varscan2
- OBSCN | c.7119C>T p.F2373= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs745471202, COSV99483982; called by muse, mutect2, varscan2
- OPN5 | c.636G>A p.T212= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV99790030; called by muse, mutect2
- OR10H5 | c.24C>T p.S8= | Silent (SNP) | VAF 39/196 reads (20%) | catalogued as rs776309210, COSV58279465; called by muse, mutect2, varscan2
- PACSIN1 | c.981G>A p.A327= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1490939597, COSV55058923; called by muse, mutect2, varscan2
- PCDHA1 | c.300G>A p.A100= | Silent (SNP) | VAF 42/156 reads (27%) | catalogued as COSV100974462; called by muse, varscan2
- PCDHB10 | c.1809G>A p.S603= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV99505003; called by muse, mutect2, varscan2
- PCDHGB6 | c.735C>T p.D245= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99546349; called by muse, mutect2, varscan2
- PHRF1 | c.2604G>A p.P868= (on ENST00000264555 / NM_001286581.2; = p.P867= on NM_020901.4) | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as rs541916891, COSV99213389; called by muse, mutect2, varscan2
- PKD1 | c.11091C>T p.H3697= (on ENST00000262304 / NM_001009944.3; = p.H3696= on NM_000296.4) | Silent (SNP) | VAF 27/183 reads (15%) | catalogued as rs1485507155, CD1210719, COSV51921640; called by muse, mutect2, varscan2
- PTCH2 | c.2811C>T p.A937= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs375965470; called by muse, mutect2, varscan2
- RAB11FIP1 | c.288G>A p.A96= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99770449; called by muse, mutect2, varscan2
- RAD51AP2 | c.1737A>T p.L579= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV101208408, COSV67587907; called by muse, mutect2, varscan2
- RANBP10 | c.795C>T p.L265= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs767427091, COSV100449474; called by muse, mutect2
- RHBDF1 | c.927C>T p.S309= | Silent (SNP) | VAF 16/242 reads (7%) | catalogued as rs560942763, COSV99245107; called by muse, mutect2
- RPS6KL1 | c.1386G>A p.T462= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs774897997, COSV100665214; called by muse, mutect2, varscan2
- SAXO2 | c.1131C>T p.F377= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs762093678, COSV100255905; called by muse, mutect2, varscan2
- SFXN1 | c.123C>T p.N41= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs376235466; called by muse, mutect2, varscan2
- SLC1A1 | c.279C>T p.R93= | Silent (SNP) | VAF 24/361 reads (7%) | catalogued as rs747351979, COSV99261576; called by muse, mutect2
- SLC25A48 | c.597C>T p.Y199= (on ENST00000650267; = p.Y145= on NM_001349335.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as rs746489691, COSV50853058; called by muse, mutect2, varscan2
- SLC38A8 | c.426G>A p.P142= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs201965163, COSV55304247; called by muse, mutect2, varscan2
- SLCO3A1 | c.1791C>T p.I597= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs150046342; called by muse, mutect2, varscan2
- SNX8 | c.741C>T p.I247= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs747318950, COSV56126363; called by muse, mutect2, varscan2
- SPG21 | c.873C>T p.A291= | Silent (SNP) | VAF 56/171 reads (33%) | catalogued as COSV99200206; called by muse, mutect2, varscan2
- SRP72 | c.132C>T p.D44= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as rs530644774, COSV100714375, COSV61379184; called by muse, mutect2, varscan2
- STYXL2 | c.1386C>T p.H462= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1318279497, COSV99608846; called by muse, mutect2, varscan2
- SV2A | c.1473C>T p.R491= | Silent (SNP) | VAF 95/223 reads (43%) | catalogued as rs782094239, COSV64965958; called by muse, mutect2, varscan2
- TANC1 | c.1422C>T p.S474= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV55083018; called by muse, mutect2, varscan2
- TIAM1 | c.405C>T p.Y135= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs151048315, COSV54554850, COSV54558965; called by muse, mutect2, varscan2
- TNFSF9 | c.528C>T p.A176= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1420949230, COSV99832470; called by muse, varscan2
- TTC21A | c.738C>T p.S246= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as COSV100087650; called by muse, mutect2, varscan2
- UBE3C | c.1293G>A p.T431= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs990859814, COSV100780079; called by muse, mutect2, varscan2
- ZBTB20 | c.2100C>T p.R700= (on ENST00000474710 / NM_001164342.2; = p.R627= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as rs772866543, COSV100615145; called by muse, mutect2, varscan2
- ZMIZ2 | c.864C>T p.T288= | Silent (SNP) | VAF 81/388 reads (21%) | catalogued as rs543600015, COSV54807765; called by muse, mutect2, varscan2
- ZNF605 | c.1692C>T p.S564= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as rs746347356, COSV59159384; called by muse, mutect2, varscan2
- ZSCAN1 | c.183G>A p.T61= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs534604065, COSV56608844; called by muse, mutect2, varscan2
- DNAJC5 | c.-11-8852C>T | Intron (SNP) | VAF 12/74 reads (16%) | catalogued as rs756328807, COSV62670691; called by muse, varscan2
- FABP5P3 | chr7:152446250 G>A | 3'Flank (SNP) | VAF 18/265 reads (7%) | catalogued as rs776608171; called by muse, mutect2
- MELTF | c.712+1677C>T | Intron (SNP) | VAF 55/126 reads (44%) | catalogued as rs756325952, COSV56384045, COSV99585970; called by muse, mutect2, varscan2
- PAX3 | chr2:222201413 C>T | 3'Flank (SNP) | VAF 28/85 reads (33%) | catalogued as rs753282124, COSV60590085; called by muse, mutect2, varscan2
- PISD | c.322-3910G>A | Intron (SNP) | VAF 6/21 reads (29%) | catalogued as rs529155691, COSV99837149; called by muse, mutect2, varscan2
